Gene-level copy-number profile of tumor specimen TCGA-L5-A4OU-01A from TCGA case TCGA-L5-A4OU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 81.2 years (29,674 days).
Specimen TCGA-L5-A4OU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.66037c67-bcdf-418b-9b5f-74d741c08120.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OU-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7af03e2e-5d6b-4e01-a856-7aec4a8be448

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 1,638; copy number 2: 4,766; copy number 3: 29,819; copy number 4: 18,487; copy number 5: 1,137; copy number 6: 2,854; copy number 7: 437; copy number 8: 4; copy number 9: 100; copy number 13: 204; copy number 21: 59; copy number 25: 204.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OU-01A-11D-A28A-01): tumor purity 0.35, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr7:110,108,031–117,874,139, 105 genes (within-gene range 0–3) (broad region; genes not listed).
- chr7:119,495,024–120,227,213, 4 genes: LINC02476, RNU1-29P, AC004946.1, AC004946.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,008 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:71,779,491–72,447,151, 1 gene, copy number 7 (within-gene range 4–7): CALN1.
- chr7:72,103,181–74,760,692, 77 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:83,355,154–83,649,139, 4 genes, copy number 7 (within-gene range 4–7): AC079799.1, SEMA3E, AC079799.2, AC079987.1.
- chr7:87,934,143–102,809,225, 366 genes, copy number 13–25 (within-gene range 3–25) (broad region; genes not listed).
- chr7:141,907,813–142,106,747, 1 gene, copy number 8 (within-gene range 4–8): MGAM.
- chr7:141,927,357–142,222,324, 3 genes, copy number 8 (within-gene range 2–8): CLEC5A, TAS2R38, MGAM2.
- chr7:145,583,197–145,584,817, 1 gene, copy number 7: DPY19L4P2.
- chr11:68,903,863–71,863,658, 90 genes, copy number 13–21 (broad region; genes not listed).
- chr12:23,175,648–28,581,511, 100 genes, copy number 9 (broad region; genes not listed).
- chr17:39,603,536–39,747,291, 11 genes, copy number 25: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:58,660,424–58,692,018, 1 gene, copy number 7 (within-gene range 3–7): IGBP1P2.
- chr17:58,675,286–72,058,073, 353 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,630. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
